Surgical pathology report (de-identified scan), TCGA case TCGA-75-5146, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Ontario Institute for Cancer Research (OICR), specimen TCGA-75-5146-01A (Primary Tumor).

Sample Number	Sample Type	Sample Preparation	Site of Tissue	Diagnosis	Year of Sample Collection	Age at Sample Collection (yrs)	Sample Comments	Days to Procedure Date	Core ID	Type of Procedure	Site of Primary (Histology)	Tumour Size (cm)	Histology	Grade/ Differentiation	Pathological T	Pathological N	Clinical M	YALCSG Stage	Histology Comments	Slide Image
	TUMOUR	FF	RL	Adenocarcinoma						RESECT	RL	6.00	03	I	T2,NOS	N0	M0			
	BIOPSY	FF		Adenocarcinoma						RESECT	RL	6.00	03	I	T2,NOS	N0	M0			

Source: NCI Genomic Data Commons file 802faf8f-f764-42c1-8da7-a3d13c3d1901 (TCGA-75-5146.5EE0C2C4-3441-46D7-944E-3267F5C3ABB6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).